Somatic mutation profile of tumor specimen TCGA-55-8090-01A (aliquot TCGA-55-8090-01A-11D-2238-08) from TCGA case TCGA-55-8090, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 80.0 years (29,235 days).
Specimen TCGA-55-8090-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c850269-c292-4b95-a22a-3e6cb8e54b18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8090-10A (Blood Derived Normal), aliquot TCGA-55-8090-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef78dde5-6e3d-45f9-ae5c-59b2ccdd867d

The open-access MAF lists 96 somatic variants for this specimen: 74 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 20, Nonsense Mutation 5, Splice Site 4, RNA 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100929500, COSV63672239; called by muse, mutect2, varscan2
- ADAMTS9 | c.2420T>C p.L807P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99898983; called by muse, mutect2, varscan2
- ANK1 | c.2902G>T p.E968* | Nonsense Mutation (SNP) | VAF 19/106 reads (18%) | catalogued as COSV55882775, COSV99224456; called by muse, varscan2
- BNC1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV100596997; called by muse, mutect2, varscan2
- CAND2 | c.1054C>G p.R352G (on ENST00000456430 / NM_001162499.2; = p.R259G on NM_012298.3) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755379183, COSV99928475, COSV99928782; called by muse, mutect2, varscan2
- CAV3 | c.96T>G p.I32M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as COSV100664334; called by muse, mutect2
- CCDC146 | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592314; called by muse, mutect2, varscan2
- CCDC88A | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | catalogued as COSV99709963; called by muse, mutect2, varscan2
- CDX4 | c.20T>C p.L7S | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs746867826, COSV100999119; called by muse, mutect2, varscan2
- CGREF1 | c.718+2G>A p.X240_splice (on ENST00000260595; = p.G240= on NM_006569.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 82/312 reads (26%) | catalogued as rs568373617, COSV53148390; called by muse, varscan2
- CRHBP | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99169459; called by muse, mutect2, varscan2
- CSMD3 | c.2030G>C p.G677A (on ENST00000297405 / NM_001363185.1; = p.G573A on NM_052900.3) | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52122496, COSV99828380, COSV99840786; called by muse, mutect2, varscan2
- CYP4A11 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV60226371; called by muse, mutect2, varscan2
- DCHS1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100201701; called by muse, mutect2, varscan2
- DHX9 | c.1735A>G p.I579V | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.175); catalogued as COSV100841286; called by muse, mutect2, varscan2
- EID1 | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100194301; called by muse, mutect2, varscan2
- FAM71D | c.689A>T p.D230V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV100315139; called by muse, mutect2, varscan2
- FAP | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 42/110 reads (38%) | catalogued as COSV99501904; called by muse, mutect2, varscan2
- FIGNL1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63554272; called by muse, mutect2, varscan2
- FLT1 | c.2877C>A p.S959R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.066); catalogued as COSV99150424; called by muse, mutect2, varscan2
- FNDC7 | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99601006; called by muse, mutect2, varscan2
- FOXP1 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100561292; called by muse, mutect2, varscan2
- FRMD4B | c.2519G>T p.R840L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV101273375; called by muse, varscan2
- FZD9 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.316); catalogued as rs782339488, COSV59988261; called by muse, mutect2, varscan2
- GRID2 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as COSV99938688; called by muse, mutect2
- GRIN2B | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs776323617, COSV74208162; called by muse, mutect2, varscan2
- GRM1 | c.454A>T p.T152S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.023); catalogued as COSV99264834, COSV99268849; called by muse, mutect2, varscan2
- HCFC2 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV99982935; called by muse, mutect2, varscan2
- HELZ | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV100698577, COSV62379668; called by muse, mutect2, varscan2
- HNRNPH2 | c.265A>G p.N89D | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV99516241; called by muse, mutect2, varscan2
- HUWE1 | c.11621A>T p.H3874L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99471148; called by muse, mutect2, varscan2
- KLHL14 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV100839105, COSV63832661; called by muse, mutect2, varscan2
- KLHL18 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99230652; called by muse, mutect2, varscan2
- KRTAP24-1 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs753490829, COSV100447362, COSV100447521; called by muse, mutect2, varscan2
- L3MBTL4 | c.383G>T p.W128L | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53118014, COSV99527933; called by muse, mutect2, varscan2
- MSL3 | c.1373G>A p.R458Q (on ENST00000312196 / NM_078629.4; = p.R292Q on NM_006800.4) | Missense Mutation (SNP) | VAF 81/119 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV56491919; called by muse, mutect2, varscan2
- NDST3 | c.2315T>A p.L772Q | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99629938; called by muse, mutect2, varscan2
- NDUFAF1 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1566825675, COSV99531346; called by muse, mutect2, varscan2
- NEDD4L | c.922T>C p.S308P | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV99893885; called by muse, mutect2, varscan2
- NELL1 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100119830; called by muse, mutect2, varscan2
- NKX3-2 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as COSV101219856; called by muse, mutect2, varscan2
- NOS1AP | c.1250G>T p.S417I | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV100722963, COSV62635819; called by muse, mutect2, varscan2
- OR10H2 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100008660, COSV59947085; called by muse, mutect2, varscan2
- OR10K1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as COSV99193308; called by muse, mutect2, varscan2
- OR51I2 | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.885); catalogued as COSV100413334; called by muse, mutect2, varscan2
- PCNX2 | c.4226G>T p.R1409L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99266532; called by muse, mutect2, varscan2
- PDGFRB | c.1053C>G p.F351L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99940314; called by muse, mutect2, varscan2
- POU6F2 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101302556; called by muse, mutect2, varscan2
- PRUNE2 | c.3991C>A p.Q1331K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100944319; called by muse, mutect2, varscan2
- RAD51AP2 | c.643A>G p.N215D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101208303; called by muse, mutect2, varscan2
- RBM10 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 18/27 reads (67%) | catalogued as COSV61310790; called by muse, mutect2, varscan2
- RPAP3 | c.1286C>G p.T429S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV99139302; called by muse, mutect2, varscan2
- SAMD9L | c.4186A>G p.N1396D | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV100560475; called by muse, mutect2, varscan2
- SIGLEC6 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100585226; called by muse, mutect2, varscan2
- SLC6A14 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs782477666, COSV100903094; called by muse, mutect2, varscan2
- SMTN | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100294129; called by muse, mutect2, varscan2
- SNRPN | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100577988, COSV57598536; called by muse, mutect2, varscan2
- SPINK2 | c.99+1G>A p.X33_splice | Splice Site (SNP) | VAF 18/77 reads (23%) | catalogued as COSV99954181; called by muse, mutect2, varscan2
- TENM4 | c.4621T>A p.S1541T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99572419; called by muse, mutect2, varscan2
- TGM2 | c.1913+2T>A p.X638_splice | Splice Site (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100821531; called by muse, mutect2, varscan2
- TH | c.260C>A p.A87E (on ENST00000381178 / NM_199292.3; = p.A56E on NM_000360.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100147063; called by muse, mutect2, varscan2
- TRA2B | c.564G>C p.R188S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs1360796973, COSV99373214; called by muse, mutect2, varscan2
- TTI1 | c.1783A>G p.I595V | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100989604; called by muse, mutect2, varscan2
- TTK | c.1724T>G p.L575W | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036109; called by muse, mutect2, varscan2
- TUB | c.178C>T p.R60W (on ENST00000299506 / NM_177972.3; = p.R115W on NM_003320.4) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs1415875110, COSV100210094; called by muse, mutect2, varscan2
- UNC5C | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV101497815; called by muse, mutect2, varscan2
- ZNF92 | c.864A>T p.E288D (on ENST00000328747 / NM_152626.4; = p.E219D on NM_007139.4) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV100165714; called by muse, mutect2, varscan2
- DEK | c.145+2_145+3del p.X49_splice | Splice Site (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- FAM126A | c.581del p.Y194Sfs*27 | Frame Shift Del (DEL) | VAF 45/180 reads (25%) | called by mutect2, pindel, varscan2
- LTN1 | c.2962del p.E988Nfs*4 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- STK16 | c.685_687del p.M229del | In Frame Del (DEL) | VAF 26/100 reads (26%) | called by pindel, varscan2
- TRBJ2-6 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- XKR3 | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.234); called by muse, mutect2
- ACSM2A | c.342C>A p.P114= (on ENST00000219054; = p.P35= on NM_001308169.2) | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs1275425442, COSV99525034; called by muse, varscan2
- COL6A3 | c.6423T>C p.P2141= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV99796712; called by muse, mutect2, varscan2
- CTPS1 | c.1683C>T p.L561= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as COSV101009299, COSV65453639; called by muse, mutect2, varscan2
- DNAH5 | c.996T>C p.I332= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV99446549; called by muse, mutect2, varscan2
- FUT8 | c.501A>T p.L167= (on ENST00000360689 / NM_001371534.1; = p.L4= on NM_004480.4) | Silent (SNP) | VAF 69/211 reads (33%) | catalogued as COSV100651196; called by muse, mutect2, varscan2
- OR2L13 | c.648C>A p.S216= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100813698; called by muse, mutect2, varscan2
- OR4C6 | c.750C>T p.V250= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as rs755348905, COSV100051475; called by muse, mutect2, varscan2
- PTPRG | c.3585A>C p.A1195= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99873763; called by muse, mutect2, varscan2
- PUM1 | c.1383T>C p.Y461= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1456537634, COSV99927673; ClinVar: likely benign; called by muse, mutect2
- RAPGEF2 | c.4293C>G p.A1431= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100030774; called by muse, mutect2
- RNF213 | c.6711G>T p.P2237= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV100300000; called by muse, mutect2, varscan2
- RRAGD | c.1110G>A p.V370= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100784510; called by muse, mutect2, varscan2
- SCAF1 | c.3840C>T p.H1280= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs575013180, COSV59191653; called by muse, mutect2, varscan2
- SEMA3D | c.1761C>A p.I587= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV52408889, COSV99406140; called by muse, mutect2, varscan2
- SEMA5A | c.2601T>A p.S867= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV101227431; called by muse, mutect2, varscan2
- SMC1B | c.867C>T p.T289= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100663073; called by muse, mutect2, varscan2
- SSX2IP | c.810C>T p.I270= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100642509; called by muse, mutect2, varscan2
- SULF2 | c.270C>T p.P90= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV100737064; called by muse, mutect2, varscan2
- UBN1 | c.1992C>T p.D664= | Silent (SNP) | VAF 50/203 reads (25%) | catalogued as COSV99277652; called by muse, mutect2, varscan2
- VPS13D | c.4638A>G p.L1546= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs1340422710, COSV99165784; called by muse, mutect2, varscan2
- MIR1185-2 | n.63G>T | RNA (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- MIR573 | n.51G>C | RNA (SNP) | VAF 99/319 reads (31%) | called by muse, mutect2, varscan2
